Somatic mutation profile of tumor specimen MMRF_1169_1_BM_CD138pos (aliquot MMRF_1169_1_BM_CD138pos_T9_KHS5U_L09545) from MMRF case MMRF_1169, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.9 years (27,363 days).
Specimen MMRF_1169_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dee9dee9-df83-4f88-a3b7-60bdb58bb0b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1169_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1169_1_PB_CD3pos_C1_KHS5U_L08641; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ba0219a-866f-49ae-8d5d-682641e1d5b4

The open-access MAF lists 24 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'UTR 6, Intron 3, Silent 2, Splice Region 1, 5'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM19 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.253); catalogued as COSV57430458; called by muse, mutect2, varscan2
- CEP120 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs773832163; called by muse, mutect2, varscan2
- SYNE1 | c.4823C>T p.A1608V (on ENST00000367255 / NM_182961.4; = p.A1615V on NM_033071.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1388098323, COSV54958316; called by muse, mutect2, varscan2
- AP5S1 | c.378_379delinsC p.D127Mfs*16 | Frame Shift Del (DEL) | VAF 55/262 reads (21%) | called by pindel, varscan2*
- CDC42BPG | c.2355G>T p.Q785H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PCDH10 | c.2691-6T>C | Splice Region (SNP) | VAF 46/145 reads (32%) | called by muse, mutect2, varscan2
- PTPRO | c.75+2T>C p.X25_splice | Splice Site (SNP) | VAF 28/82 reads (34%) | called by muse, varscan2
- RNF217 | c.153C>G p.S51R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); called by muse, varscan2
- SPHKAP | c.3519C>A p.H1173Q | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBR3 | c.1452A>C p.K484N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VSIG10L2 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZNF730 | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, varscan2
- PCLO | c.8619T>A p.T2873= | Silent (SNP) | VAF 39/157 reads (25%) | called by muse, mutect2, varscan2
- ZNF730 | c.1353C>G p.P451= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV74168474; called by muse, varscan2
- BMP5 | c.-300C>T | 5'UTR (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- DNAJB9 | c.*424C>G | 3'UTR (SNP) | VAF 15/72 reads (21%) | called by muse, varscan2
- HAPLN1 | c.*2209A>C | 3'UTR (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- KIF15 | c.*368G>A | 3'UTR (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- NAPB | c.*682_*686delinsATGCG | 3'UTR (ONP) | VAF 3/35 reads (9%) | called by mutect2*, pindel
- PCDH7 | c.*670A>T | 3'UTR (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- PNPLA6 | c.-42-118_-42-107del | Intron (DEL) | VAF 34/159 reads (21%) | called by mutect2, varscan2
- PNPO | c.417+310C>G | Intron (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- PREX2 | c.2716-2956A>T | Intron (SNP) | VAF 19/37 reads (51%) | called by muse, varscan2
- SLC7A1 | c.*2249A>T | 3'UTR (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
